CDDP_EAGLE case CDDP-ACQ7 — CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/d5461b65-63ee-4211-9c8b-ee288f012402

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Year of birth: 1949; Vital status: Dead; Days to death: 1,865 days (5.1 years); Year of death: 2009; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.11; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Age at diagnosis: 55 years; Year of diagnosis: 2004; Days to diagnosis: 0 days; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,865 days (5.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Exposures
- Exposure type: Tobacco; Pack years smoked: 100; Exposure duration years: 40.

Biospecimens (2 samples)
- Sample CDDP-ACQ7-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample CDDP-ACQ7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Protocol status: Completed; Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); Cause of death: Submitted Malignancy and/or related tumor event; Height cm at diagnosis: 162 cm; Weight kg at diagnosis: 75 kg; History neoadjuvant treatment: No; Tobacco smoking history indicator: 4; Tobacco smoking year started: 1963; Tobacco smoking year stopped: 2003; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Partial Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Comorbidities: Comorbidity: Copd; Comorbidity: Diabetes; Comorbidity: Epilepsy; Comorbidity: Smoking.
- Followup history list, Followup history 1: Tumor status: Never Tumor Free.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Biopsy (all types).
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- New tumor event 1: Days from index date to new tumor event diagnosis: 1699; New tumor event type: Metastatic; New tumor event site: Bone; New event treatment outcome: Partial Response.
- New tumor event 2: Days from index date to new tumor event diagnosis: 1699; New tumor event type: Metastatic; New tumor event site other: Ipsilateral Lung; New event treatment outcome: Partial Response.
